Somatic mutation profile of tumor specimen TCGA-VS-AA62-01A (aliquot TCGA-VS-AA62-01A-11D-A42O-09) from TCGA case TCGA-VS-AA62, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 51.4 years (18,792 days).
Specimen TCGA-VS-AA62-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e5e9227-dd1d-451c-8c41-f3442c90b860.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-AA62-10A (Blood Derived Normal), aliquot TCGA-VS-AA62-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d0b5fe7-8a2e-472b-9895-069cfa0e8dbf

The open-access MAF lists 97 somatic variants for this specimen: 74 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 69, Silent 23, Nonsense Mutation 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.068); catalogued as rs28936684, CM950203, CM950204, COSV56134756; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT3 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs747639500, COSV52882933, COSV52884030, COSV52885662; called by muse, mutect2, varscan2
- AGO3 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99868850; called by muse, mutect2, varscan2
- AHSA1 | c.998A>G p.Y333C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); catalogued as COSV99376085; called by muse, mutect2, varscan2
- ALG10 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as rs1437828204, COSV99848212; called by muse, mutect2, varscan2
- APC | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1485974418, CD941573, COSV99968535; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGAP1 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100796639; called by muse, mutect2, varscan2
- ATP1A3 | c.488C>T p.S163F (on ENST00000545399 / NM_001256214.2; = p.S150F on NM_152296.5) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100132337; called by muse, mutect2, varscan2
- ATP1A4 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs779315936, COSV100927587, COSV63629013; called by muse, mutect2, varscan2
- ATP6V1G3 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99810932; called by muse, mutect2, varscan2
- CATSPERG | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV99286654; called by muse, varscan2
- CDHR2 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99991783; called by muse, mutect2, varscan2
- CTC1 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs1203574273, COSV100236539; called by muse, mutect2, varscan2
- DACH2 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100913465; called by muse, mutect2
- DCAF8 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as COSV100470558; called by muse, mutect2, varscan2
- DNMT1 | c.3930G>C p.R1310S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100532636; called by muse, mutect2, varscan2
- DOCK5 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99377173; called by muse, mutect2, varscan2
- FAM98A | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.969); catalogued as COSV99479379, COSV99479541; called by muse, mutect2
- FMO5 | c.451C>G p.H151D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99567190; called by muse, mutect2
- GATM | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.123); catalogued as rs1193533349, COSV67540500; called by muse, mutect2, varscan2
- GOLGA2 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100199696; called by muse, mutect2, varscan2
- HDLBP | c.3471C>G p.F1157L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs765922546, COSV100191106; called by muse, mutect2, varscan2
- IGDCC4 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370454461, COSV61536571; called by muse, mutect2, varscan2
- IGSF22 | c.2419G>T p.D807Y (on ENST00000319338; = p.D908Y on NM_173588.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as COSV99773794; called by muse, mutect2
- ITGAX | c.476C>G p.S159* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs778576565, COSV99191810; called by muse, mutect2, varscan2
- JMY | c.2633C>T p.T878I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101268048; called by muse, mutect2, varscan2
- KCNC3 | c.1275C>G p.F425L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100979285; called by muse, mutect2
- KDM3B | c.3047-1G>C p.X1016_splice | Splice Site (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100069850; called by muse, mutect2, varscan2
- KIAA1217 | c.2175G>C p.L725F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100286830; called by muse, mutect2, varscan2
- KLHL12 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100935724; called by muse, mutect2, varscan2
- LGI1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV101004435, COSV65058105; called by muse, mutect2, varscan2
- LUZP2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs761957446, COSV61218705; called by mutect2, varscan2
- MAGT1 | c.50C>T p.A17V (on ENST00000618282 / NM_001367916.1; = p.A49V on NM_032121.5) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV63780886; called by muse, mutect2, varscan2
- MAP1B | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99702577; called by muse, mutect2
- MED14 | c.3622G>C p.E1208Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100247530; called by muse, mutect2
- MMP24 | c.1767C>G p.I589M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV99863930; called by muse, mutect2, varscan2
- MPHOSPH10 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54905455, COSV99731168; called by muse, mutect2
- NPEPL1 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100622459; called by muse, mutect2, varscan2
- NUP153 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.703); catalogued as COSV100020491; called by muse, mutect2
- NUSAP1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs745709236, COSV52970673, COSV52970918; called by muse, mutect2, varscan2
- PASK | c.3790G>C p.E1264Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV99299708; called by muse, mutect2, varscan2
- PREX2 | c.2722C>G p.R908G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV99908118; called by muse, mutect2, varscan2
- PRKAR2B | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1326909416, COSV55925772, COSV99708791; called by muse, mutect2, varscan2
- PXN | c.1143C>G p.H381Q (on ENST00000228307 / NM_001080855.3; = p.H347Q on NM_002859.4) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99936027; called by muse, mutect2, varscan2
- R3HCC1L | c.808C>G p.P270A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.287); catalogued as COSV100107401; called by muse, mutect2, varscan2
- RMC1 | c.1148G>T p.R383I | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99340239; called by muse, mutect2, varscan2
- SAGE1 | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100187529; called by muse, mutect2
- SAYSD1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1364044172, COSV100010198; called by muse, mutect2
- SCN9A | c.817C>A p.H273N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100313320; called by muse, mutect2, varscan2
- SMARCAD1 | c.2202G>C p.K734N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758969; called by muse, mutect2, varscan2
- SUPT6H | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV100112531; called by muse, mutect2, varscan2
- TCOF1 | c.1094C>T p.S365L (on ENST00000377797 / NM_001135243.1; = p.S288L on NM_000356.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.26); catalogued as rs1329807099, COSV100077739; called by muse, mutect2, varscan2
- TMEM245 | c.2087C>G p.S696C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs763188586, COSV101002376; called by mutect2, varscan2
- TMPRSS9 | c.3244G>A p.A1082T (on ENST00000648592; = p.A1048T on NM_182973.2) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs757317254, COSV99296018; called by muse, mutect2, varscan2
- TNFAIP8 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99174279; called by muse, mutect2, varscan2
- TOP2B | c.670G>C p.E224Q (on ENST00000264331 / NM_001330700.2; = p.E219Q on NM_001068.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as COSV99979893; called by muse, mutect2, varscan2
- TRAJ45 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs375707150; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); catalogued as rs941991102, COSV100935835; called by muse, mutect2
- TRIP11 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV99970822; called by muse, mutect2, varscan2
- TTLL7 | c.2362G>C p.D788H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV99552582; called by muse, mutect2, varscan2
- TUBD1 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV100360161; called by muse, mutect2, varscan2
- TUT7 | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99463227; called by muse, mutect2, varscan2
- UBC | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV100299029; called by muse, mutect2, varscan2
- UBC | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV60058140; called by muse, mutect2
- WASF3 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.424); catalogued as COSV100098891, COSV58971400; called by muse, mutect2
- ZC3H12C | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV99585104; called by muse, mutect2, varscan2
- ZFAT | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV100914746, COSV100915152; called by muse, mutect2, varscan2
- ZNF292 | c.4385C>T p.S1462L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs757750690, COSV100370607; called by muse, mutect2, varscan2
- ZNF518A | c.379A>G p.N127D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100283581; called by muse, mutect2, varscan2
- ZSCAN4 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755068043, COSV56591318; called by muse, mutect2
- LMF2 | c.1046G>C p.R349T | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- OBSCN | c.8487C>G p.I2829M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RDH11 | c.454+2del p.X152_splice | Splice Site (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- SMC4 | c.2267G>C p.S756T | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2
- BRCA2 | c.9087G>A p.A3029= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs368576266; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- CDH26 | c.336G>A p.E112= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV54843565, COSV99722664; called by muse, mutect2, varscan2
- CLEC4F | c.1587C>T p.L529= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99713805; called by muse, mutect2, varscan2
- CTC1 | c.735C>T p.F245= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100236541; called by muse, mutect2, varscan2
- DAAM1 | c.423G>A p.L141= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs1336280629, COSV100658498; called by muse, mutect2, varscan2
- DYNC2LI1 | c.423G>C p.V141= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99571308; called by muse, mutect2, varscan2
- KCNC3 | c.924C>T p.C308= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100979286, COSV65388405; called by muse, mutect2, varscan2
- KDM2B | c.1527C>A p.L509= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100997470, COSV65643349; called by muse, mutect2, varscan2
- KIF14 | c.1812G>T p.L604= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100950938; called by muse, mutect2, varscan2
- LHCGR | c.453C>T p.F151= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV54299618, COSV99683624; called by muse, mutect2
- NUP62 | c.1434C>G p.L478= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100352160; called by muse, mutect2, varscan2
- PACS1 | c.2028C>T p.V676= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs774305002, COSV100270215; called by muse, mutect2, varscan2
- POU5F2 | c.369G>A p.L123= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV101232823; called by muse, varscan2
- PRR5 | c.612C>T p.V204= (on ENST00000336985 / NM_181333.4; = p.V195= on NM_015366.4) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs1232111417, COSV99134511; called by muse, mutect2, varscan2
- RALBP1 | c.195G>A p.E65= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs201145450, COSV99191972; called by muse, mutect2, varscan2
- SBF1 | c.3312G>C p.L1104= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- SGPL1 | c.1398G>A p.L466= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100940397; called by muse, mutect2, varscan2
- SLC2A1 | c.1101G>C p.L367= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs780853763, COSV100995901; called by muse, mutect2, varscan2
- TLR8 | c.2262C>T p.S754= (on ENST00000218032 / NM_138636.5; = p.S772= on NM_016610.4) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs372127380, COSV54318971; called by muse, mutect2, varscan2
- TSHZ2 | c.3003G>A p.R1001= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV61590785; called by muse, mutect2, varscan2
- UGGT2 | c.309C>T p.I103= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100942596; called by muse, mutect2, varscan2
- XIRP2 | c.3798C>A p.V1266= (on ENST00000628543; = p.V1441= on NM_152381.6) | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs780923990, COSV54710975, COSV99744352; called by muse, mutect2, varscan2
- ZNF3 | c.351A>G p.Q117= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs749121645, COSV99447316; called by muse, mutect2, varscan2
